Somatic mutation profile of tumor specimen TCGA-NH-A8F8-01A (aliquot TCGA-NH-A8F8-01A-72D-A40P-10) from TCGA case TCGA-NH-A8F8, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 79.9 years (29,185 days).
Specimen TCGA-NH-A8F8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03b594c6-cad8-432b-85a0-6d00d98039c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A8F8-10A (Blood Derived Normal), aliquot TCGA-NH-A8F8-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f2e48f4-ffde-486a-850a-5c1a86e40dd0

The open-access MAF lists 109 somatic variants for this specimen: 87 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 71, Silent 22, Nonsense Mutation 9, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 33/55 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.1958+1G>A p.X653_splice | Splice Site (SNP) | VAF 33/96 reads (34%) | catalogued as rs1114167569, CD014920, CS011023, CS011024, HS080016, COSV57330281, COSV57355367; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 40/134 reads (30%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.9235C>T p.R3079* | Nonsense Mutation (SNP) | VAF 71/203 reads (35%) | catalogued as rs1175877764, COSV54263522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 47/169 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACRV1 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59754541; called by muse, mutect2, varscan2
- ADARB2 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV101186717; called by muse, mutect2
- AGAP2 | c.3439G>C p.G1147R (on ENST00000547588 / NM_001122772.2; = p.G791R on NM_014770.4) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99222383; called by muse, mutect2, varscan2
- AMER1 | c.1735G>T p.E579* | Nonsense Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100365513; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6610T>A p.F2204I | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99782322; called by muse, mutect2, varscan2
- C2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs771081314, COSV54961484; called by muse, mutect2, varscan2
- CACNA1H | c.1696C>A p.P566T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs891039616, COSV100671066; called by muse, mutect2, varscan2
- CEBPZ | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99135444; called by muse, mutect2, varscan2
- CHD4 | c.1203+1G>A p.X401_splice (on ENST00000357008 / NM_001363606.2; = p.X414_splice on NM_001273.5) | Splice Site (SNP) | VAF 15/82 reads (18%) | catalogued as COSV58895476; called by muse, mutect2, varscan2
- CNTN1 | c.2385C>A p.Y795* | Nonsense Mutation (SNP) | VAF 52/161 reads (32%) | catalogued as rs1389946952, COSV100751035; called by muse, mutect2, varscan2
- CPQ | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99610838; called by muse, mutect2, varscan2
- CR1 | c.5230C>T p.R1744* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as rs55749440, COSV65457864; called by muse, mutect2, varscan2
- DCC | c.66G>T p.L22F | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV101472452; called by muse, mutect2, varscan2
- DNAH17 | c.11326G>A p.G3776R | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs954658523, COSV67750069; called by muse, mutect2, varscan2
- DNAI1 | c.1189T>C p.Y397H | Missense Mutation (SNP) | VAF 95/178 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV99646605; called by muse, mutect2, varscan2
- DPYSL5 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs1367629354, COSV99981877; called by muse, mutect2, varscan2
- ERBB4 | c.1927A>T p.T643S | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.899); catalogued as COSV99617906; called by muse, mutect2, varscan2
- FBLN1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs772445995, COSV53044161, COSV53049144; called by muse, mutect2, varscan2
- FBN3 | c.3287G>T p.C1096F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99560100; called by muse, mutect2, varscan2
- FIZ1 | c.1148A>G p.E383G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1174913172, COSV99684473; called by muse, mutect2, varscan2
- GAL3ST4 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.282); catalogued as COSV100385382, COSV100385498; called by muse, mutect2, varscan2
- GIGYF1 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs749853452, COSV99308917; called by muse, mutect2, varscan2
- GK2 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV62626715; called by muse, mutect2, varscan2
- GPR12 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 69/120 reads (58%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV67344734; called by muse, mutect2, varscan2
- GPR6 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.572); catalogued as rs1488665352, COSV51571468; called by muse, mutect2, varscan2
- GPRC6A | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs144356533, COSV59951396; called by muse, mutect2, varscan2
- HIPK1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV65783424, COSV65785561; called by muse, mutect2, varscan2
- HS6ST2 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 58/77 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV63710902; called by muse, mutect2, varscan2
- IL17RD | c.1630G>A p.V544I | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as rs1211531264, COSV99576670; called by muse, mutect2, varscan2
- ISL2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs868732634, COSV99320536; called by muse, mutect2, varscan2
- KCNC2 | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.772); catalogued as rs773066026, COSV100128363; called by muse, mutect2, varscan2
- KCNK15 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1181815975, COSV100865085; called by muse, mutect2, varscan2
- KLHL30 | c.162C>A p.S54R | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV100014043; called by muse, mutect2, varscan2
- KMT2B | c.2992C>T p.Q998* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99718981; called by muse, mutect2, varscan2
- LAMA2 | c.3547C>T p.R1183W | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs867302949, COSV70352888; called by muse, mutect2, varscan2
- LIMS2 | c.490T>C p.F164L (on ENST00000355119 / NM_001161403.3; = p.F188L on NM_017980.4) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99760439; called by muse, mutect2, varscan2
- LRP11 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as COSV53333123; called by muse, mutect2, varscan2
- LRP2 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99786850; called by muse, mutect2, varscan2
- MAGEB2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 100/144 reads (69%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs200649828, COSV66780593; called by muse, mutect2, varscan2
- MCC | c.750C>A p.C250* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100202159; called by muse, mutect2, varscan2
- MLH3 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as COSV99464901; called by muse, mutect2, varscan2
- MYB | c.141+1G>T p.X47_splice | Splice Site (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100214612; called by muse, mutect2, varscan2
- NLRP13 | c.2482C>A p.Q828K | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as rs1222599914, COSV100738065; called by muse, mutect2, varscan2
- NPC1L1 | c.3284C>A p.A1095E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.184); catalogued as COSV99202866; called by muse, mutect2, varscan2
- NTN4 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs748149271, COSV59222760; called by muse, mutect2, varscan2
- OR1L1 | c.967G>T p.A323S (on ENST00000373686; = p.A273S on NM_001005236.3) | Missense Mutation (SNP) | VAF 101/149 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV100542096; called by muse, varscan2
- OR2K2 | c.539C>T p.T180M (on ENST00000374428; = p.T151M on NM_205859.2) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs746812189, COSV100235136; called by muse, mutect2, varscan2
- OR4K15 | c.338G>A p.R113H (on ENST00000305051; = p.R89H on NM_001005486.1) | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139377821, COSV100520989; called by muse, mutect2, varscan2
- PBXIP1 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376731001; called by muse, mutect2, varscan2
- PCDH11X | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 183/271 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs760129843, COSV53441719, COSV53494306; called by muse, mutect2, varscan2
- PCDHA3 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs982936754, COSV63544933; called by muse, mutect2, varscan2
- PCDHB12 | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.142); catalogued as COSV99506863; called by muse, mutect2, varscan2
- PDHA2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268193370, COSV99756562; called by muse, mutect2, varscan2
- PDHA2 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54781909; called by muse, mutect2, varscan2
- PDYN | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54102172, COSV99452734; called by muse, mutect2, varscan2
- PLA2G15 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV99547098; called by muse, mutect2, varscan2
- RB1CC1 | c.1492T>G p.L498V | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99207183; called by muse, mutect2, varscan2
- RELCH | c.3391G>A p.V1131I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV99901529; called by muse, mutect2, varscan2
- RNF144A | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100305268; called by muse, mutect2, varscan2
- RSAD1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs200350428, COSV51954539; called by muse, varscan2
- SBNO2 | c.3561C>A p.S1187R | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.556); catalogued as COSV100684180; called by muse, mutect2
- SHLD1 | c.384A>T p.K128N | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100290179; called by muse, mutect2, varscan2
- SIM1 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs754625496, COSV53491160; called by muse, mutect2, varscan2
- SLC1A3 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); catalogued as rs549250283, COSV54316673, COSV99467816; called by muse, mutect2, varscan2
- SLC4A11 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs754299888, COSV101195906, COSV101196140; called by muse, mutect2, varscan2
- SLC8A2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776379610, COSV52638770, COSV52642416; called by muse, mutect2, varscan2
- SORCS1 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369334370, COSV53916488; called by muse, mutect2, varscan2
- SZT2 | c.5942G>A p.C1981Y (on ENST00000634258 / NM_001365999.1; = p.C1924Y on NM_015284.4) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100986949; called by muse, mutect2, varscan2
- TBC1D15 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330293147, COSV100041447; called by muse, mutect2, varscan2
- THSD7B | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367887495; called by muse, mutect2, varscan2
- TM4SF1 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100542955, COSV59524659; called by muse, mutect2, varscan2
- TMEM87B | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs769088454, COSV51718572; called by muse, mutect2, varscan2
- TNRC6B | c.1776del p.Y593Tfs*16 | Frame Shift Del (DEL) | VAF 38/61 reads (62%) | catalogued as COSV57289556; called by mutect2, pindel, varscan2
- TTN | c.20440C>A p.L6814I (on ENST00000591111; = p.L5887I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | PolyPhen possibly damaging (0.453); catalogued as COSV100598108; called by muse, mutect2, varscan2
- TYR | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54469089, COSV99633279; called by muse, mutect2, varscan2
- WDR1 | c.1189G>A p.D397N (on ENST00000382452; = p.D257N on NM_005112.5) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV101221075; called by muse, mutect2, varscan2
- ZNF395 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 27/37 reads (73%) | catalogued as rs766996536, COSV100733878, COSV60430809; called by muse, mutect2, varscan2
- ZNF512B | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs567244765, COSV53877347; called by muse, mutect2, varscan2
- PLCL2 | c.1794del p.E599Rfs*11 (on ENST00000615277 / NM_001144382.2; = p.E473Rfs*11 on NM_015184.5) | Frame Shift Del (DEL) | VAF 51/157 reads (32%) | called by mutect2, pindel, varscan2
- USH2A | c.3439dup p.V1147Gfs*56 | Frame Shift Ins (INS) | VAF 47/142 reads (33%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.265_272del p.S89Gfs*11 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, pindel, varscan2
- ANKRD27 | c.1884C>T p.S628= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1301660578, COSV60132317; called by muse, mutect2, varscan2
- ANKRD35 | c.528C>T p.G176= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs201831600, COSV62910848; called by muse, mutect2, varscan2
- BAZ2A | c.4464C>T p.I1488= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV51632066; called by muse, mutect2, varscan2
- CBY2 | c.807G>A p.A269= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100137411, COSV100137820; called by muse, mutect2, varscan2
- CPSF1 | c.759C>T p.P253= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs368966053; called by muse, mutect2, varscan2
- DSG2 | c.912T>C p.D304= | Silent (SNP) | VAF 82/155 reads (53%) | catalogued as COSV99852857; called by muse, mutect2, varscan2
- EEF1A2 | c.948G>A p.S316= | Silent (SNP) | VAF 19/170 reads (11%) | catalogued as rs750037526, COSV53204690; called by muse, mutect2, varscan2
- EHMT2 | c.2112G>A p.L704= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1213079131, COSV64994653; called by muse, mutect2, varscan2
- F12 | c.765G>C p.A255= | Silent (SNP) | VAF 5/101 reads (5%) | catalogued as COSV99499479; called by muse, mutect2
- GLI2 | c.1158G>A p.P386= | Silent (SNP) | VAF 71/198 reads (36%) | catalogued as rs141647925; called by muse, mutect2, varscan2
- HTT | c.7167G>A p.T2389= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs528326466, COSV100750499; called by muse, mutect2, varscan2
- MAML3 | c.924G>A p.E308= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs1471545390, COSV59071379; called by muse, mutect2, varscan2
- MOV10L1 | c.1371C>T p.R457= | Silent (SNP) | VAF 96/139 reads (69%) | catalogued as rs144983844; called by muse, mutect2, varscan2
- NEK11 | c.1455C>T p.S485= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV101272968; called by muse, mutect2, varscan2
- PCDH17 | c.2487C>T p.H829= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs752994581, COSV100931469; called by muse, mutect2, varscan2
- SEMA6A | c.3009G>A p.T1003= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs559240638, COSV56709501; called by muse, mutect2
- SOX11 | c.342C>A p.P114= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs200996693, COSV100430913, COSV58986777; called by muse, mutect2, varscan2
- SPATA31E1 | c.3012G>A p.E1004= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV100350031; called by muse, mutect2, varscan2
- SSTR4 | c.732C>T p.R244= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs369953610; called by muse, mutect2, varscan2
- STAB2 | c.1062C>T p.Y354= | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as rs749575440, COSV66333846; called by muse, mutect2, varscan2
- VPS33A | c.1170C>T p.N390= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs780391563, COSV99931231; called by muse, mutect2, varscan2
- WDR83 | c.619C>T p.L207= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99269531; called by muse, mutect2
